Somatic mutation profile of tumor specimen SM-JU33I (aliquot 7316UP-613) from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33I: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 964103c5-7493-4e1f-80e6-f5b85e9043e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105214 (Blood Derived Normal), aliquot 7316UP-613-1105214; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8d92aca-7b5f-4936-9eb2-633fab42dd83

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 107/397 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLG | c.7407C>G p.S2469R | Missense Mutation (SNP) | VAF 57/708 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as rs771465526; called by muse, mutect2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 62/484 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2, varscan2
- PENK | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs367716870; called by muse, mutect2
- POU5F1B | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.287); catalogued as COSV101197017; called by muse, mutect2
- SHROOM3 | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV56026958; called by muse, mutect2
- SUFU | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64015566; called by muse, mutect2
- TMEM200A | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1032893688, COSV51661039; called by muse, mutect2
- TRPV5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs775179978, COSV54688182; called by muse, mutect2
- VIT | c.1495G>A p.V499I (on ENST00000389975 / NM_001177969.1; = p.V514I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs773111980, COSV64899202; called by muse, mutect2
- CCDC50 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, mutect2
- GRID2 | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2
- ITGAL | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2
- LSR | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- RSPH1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); called by muse, mutect2
- CFAP61 | c.693G>A p.V231= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- GOLGA8H | c.567C>A p.A189= | Silent (SNP) | VAF 24/573 reads (4%) | called by muse, mutect2
- MSH2 | c.2400A>G p.L800= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs201298777; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign / benign; called by muse, mutect2
- PLEKHG3 | c.1986C>T p.D662= (on ENST00000394691; = p.D718= on NM_001308147.2) | Silent (SNP) | VAF 26/287 reads (9%) | called by muse, mutect2
- SPHKAP | c.1986C>T p.V662= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs61752224, COSV60872785; called by muse, mutect2
- KLC2 | c.*328C>T | 3'UTR (SNP) | VAF 10/267 reads (4%) | catalogued as rs1224502861; called by muse, mutect2
- MTRNR2L9 | n.67C>T | RNA (SNP) | VAF 6/91 reads (7%) | catalogued as rs1180018123; called by muse, mutect2
- NCAM1 | c.2456+1105C>T | Intron (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- SPINK9 | c.87+30T>C | Intron (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
